Gene-level copy-number profile of tumor specimen TCGA-13-0730-01A from TCGA case TCGA-13-0730, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 71.4 years (26,086 days).
Specimen TCGA-13-0730-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.f17ead9c-d1d3-47fa-9f19-292fb6d9cbec.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0730-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3e9db976-6827-41e1-9084-8fd8c04436ee

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,057; copy number 2: 24,904; copy number 3: 16,138; copy number 4: 12,111; copy number 5: 2,600; copy number 6: 1,439; copy number 7: 529; copy number 8: 661; copy number 10: 1; copy number 11: 74; copy number 12: 168; copy number 13: 31; copy number 14: 48; copy number 17: 22; copy number 19: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-13-0730-01): tumor purity 0.87, ploidy 3.07, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,601 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–14,992,066, 228 genes, copy number 5 (broad region; genes not listed).
- chr3:90,030,284–198,222,513, 1,806 genes, copy number 5 (broad region; genes not listed).
- chr8:36,887,456–43,030,535, 146 genes, copy number 6–11 (broad region; genes not listed).
- chr8:122,414,332–122,974,510, 10 genes, copy number 5 (within-gene range 3–5): SMILR, LINC01151, AC108136.1, AC100872.1, AC100872.2, CDK5P1, AC016405.3, AC016405.2, ZHX2, AC016405.1.
- chr9:1,151,807–26,118,408, 322 genes, copy number 5–6 (broad region; genes not listed).
- chr10:44,712–25,933,710, 430 genes, copy number 5–6 (broad region; genes not listed).
- chr12:66,767–34,249,958, 850 genes, copy number 5–12 (broad region; genes not listed).
- chr14:18,333,726–30,573,629, 529 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr17:142,789–2,749,504, 114 genes, copy number 6–8 (broad region; genes not listed).
- chr19:29,287,011–30,228,715, 22 genes, copy number 17 (within-gene range 3–17): AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1.
- chr19:38,587,641–40,629,818, 116 genes, copy number 8–19 (broad region; genes not listed).
- chr19:43,460,787–45,305,284, 104 genes, copy number 5–13 (within-gene range 3–13) (broad region; genes not listed).
- chr19:45,485,294–45,645,602, 6 genes, copy number 13: RTN2, PPM1N, VASP, OPA3, GPR4, EML2.
- chr20:28,563,850–64,313,132, 918 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,057. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
